Somatic mutation profile of tumor specimen C3L-02954-01 (aliquot CPT0161890006) from CPTAC case C3L-02954, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.5 years (19,171 days).
Specimen C3L-02954-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08b5713e-aee4-4095-a284-8f9486a99098.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02954-31 (Blood Derived Normal), aliquot CPT0162580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e21313c8-9817-44f1-8713-ab61510a1973

The open-access MAF lists 323 somatic variants for this specimen: 214 protein-altering or splice-affecting, 63 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 63, Intron 18, Nonsense Mutation 15, 3'UTR 9, Frame Shift Del 8, RNA 8, 5'Flank 6, 3'Flank 3, Splice Site 3, Splice Region 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 80/632 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.1700C>T p.P567L (on ENST00000399959; = p.P568L on NM_001356.5) | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519430, CM158051, COSV67863241; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 55/477 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100217058, COSV56857654; called by muse, mutect2, varscan2
- ACTRT1 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV64419070; called by muse, mutect2, varscan2
- ADGRA1 | c.816C>A p.F272L | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.434); catalogued as rs767993341, COSV101192692; called by muse, mutect2
- ADGRA1 | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs775429420, COSV66924890; called by muse, mutect2, varscan2
- AKAP9 | c.7181C>T p.T2394I (on ENST00000359028; = p.T2370I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as rs1182780608; called by muse, mutect2
- ANAPC7 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs926457100; called by muse, mutect2
- BBS9 | c.1709C>G p.S570* (on ENST00000242067 / NM_001348036.1; = p.S530* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/474 reads (7%) | catalogued as COSV54162297; called by muse, mutect2
- CACNA1E | c.267G>A p.P89= | Splice Region (SNP) | VAF 19/166 reads (11%) | catalogued as COSV62394424; called by muse, mutect2, varscan2
- CGNL1 | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1308928672; called by muse, mutect2, varscan2
- CHRD | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs749962652; called by muse, mutect2
- CHST15 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs1337191771, COSV60561288; called by muse, mutect2, varscan2
- CLEC3A | c.398G>T p.G133V (on ENST00000651443; = p.G124V on NM_005752.6) | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs761577363; called by muse, mutect2, varscan2
- COL24A1 | c.809C>A p.P270Q | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV65306870; called by muse, mutect2
- CPB1 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 43/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51571695, COSV99294507; called by muse, mutect2
- CRPPA | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs747345582; called by muse, mutect2, varscan2
- CSMD2 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs775463572, COSV53879418; called by muse, mutect2
- CSMD3 | c.490C>G p.H164D | Missense Mutation (SNP) | VAF 26/329 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.075); catalogued as rs748470330, COSV52162423; called by muse, mutect2
- CUL3 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 13/159 reads (8%) | catalogued as COSV52367038; called by muse, mutect2
- DEFB110 | c.66T>A p.N22K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV67017872; called by muse, mutect2
- DNAJB6 | c.478+1G>T p.X160_splice | Splice Site (SNP) | VAF 51/147 reads (35%) | catalogued as rs1437799511; called by muse, mutect2, varscan2
- DPF3 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV63499767; called by muse, mutect2
- DZIP3 | c.2086C>A p.H696N | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV64311151; called by muse, varscan2
- EPB41L4B | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV65803944; called by muse, mutect2, varscan2
- ESRP2 | c.1165G>A p.E389K (on ENST00000565858 / NM_001365264.1; = p.E379K on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/513 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs540156390, COSV52176107; called by muse, mutect2
- ESRP2 | c.766G>A p.E256K (on ENST00000565858 / NM_001365264.1; = p.E246K on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs1202499985, COSV52173084, COSV52176048; called by muse, mutect2
- FGFBP1 | c.513G>C p.R171S | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as COSV52586246; called by muse, mutect2
- GRIN3A | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs61744907; called by muse, mutect2
- GRM3 | c.2263G>T p.A755S | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64468260; called by muse, mutect2, varscan2
- HAPLN4 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52271160; called by muse, mutect2
- HAS2 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs753170315; called by muse, mutect2, varscan2
- HOATZ | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 48/336 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs758698673, COSV60440455, COSV60441567; called by muse, mutect2, varscan2
- IGHD3-3 | c.21G>C p.W7C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as rs569409957; called by muse, mutect2, varscan2
- IL2RG | c.835G>T p.V279L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as CD108809, CM131928; called by muse, mutect2, varscan2
- KCNA10 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63905272; called by muse, mutect2
- KDR | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 48/623 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV99816783; called by muse, mutect2
- KNG1 | c.923G>T p.R308I | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV53977492; called by muse, mutect2, varscan2
- LCE3A | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 84/423 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as rs547378092, COSV59550310; called by muse, mutect2, varscan2
- LRP1B | c.6641C>T p.P2214L | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs776804871, COSV67215308, COSV67281566; called by muse, mutect2, varscan2
- LRP1B | c.2008G>T p.D670Y | Missense Mutation (SNP) | VAF 35/298 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as COSV67186118; called by muse, mutect2, varscan2
- MAP7 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1010045555; called by muse, mutect2, varscan2
- MBD5 | c.1961A>G p.D654G | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs115495710; called by muse, mutect2, varscan2
- MEA1 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.806); catalogued as rs1383656676; called by muse, mutect2, varscan2
- MMS22L | c.2470A>T p.M824L | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as COSV51519232; called by muse, mutect2
- NOS1 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs761071680, COSV57605914; called by muse, mutect2
- NUP205 | c.5020G>A p.A1674T | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs1043930137; called by muse, mutect2, varscan2
- OR2T1 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100822262; called by muse, mutect2, varscan2
- P3H2 | c.1703A>T p.Q568L | Missense Mutation (SNP) | VAF 43/451 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV100078085; called by muse, mutect2
- PLEC | c.10088C>G p.S3363* (on ENST00000322810 / NM_201380.4; = p.S3253* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 18/266 reads (7%) | catalogued as COSV59681366; called by muse, mutect2
- PREX2 | c.3454C>T p.H1152Y | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV55775797, COSV99906255; called by muse, mutect2
- PYCR3 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 56/618 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as rs369223174; called by muse, mutect2
- RBMS3 | c.1093T>A p.C365S (on ENST00000383767 / NM_001003793.3; = p.C347S on NM_001003792.3) | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99820071; called by muse, mutect2, varscan2
- REG1B | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV59304180; called by muse, mutect2, varscan2
- SLC22A6 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 54/564 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV64560469; called by muse, mutect2
- SPATA17 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs999642075; called by muse, mutect2
- SPG11 | c.6101G>A p.R2034Q | Missense Mutation (SNP) | VAF 43/386 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as rs750101301; called by muse, mutect2, varscan2
- SPTA1 | c.5731C>A p.P1911T | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV100934660; called by muse, mutect2, varscan2
- TAF1 | c.5315G>T p.G1772V (on ENST00000373790 / NM_138923.4; = p.G1793V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1344681270, COSV52125301; called by muse, mutect2, varscan2
- TBX15 | c.944T>G p.I315S (on ENST00000369429 / NM_001330677.2; = p.I209S on NM_152380.3) | Missense Mutation (SNP) | VAF 41/490 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV52875303; called by muse, mutect2
- TECTA | c.1568A>T p.Y523F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.56); catalogued as COSV50688564; called by muse, mutect2, varscan2
- TP53 | c.472del p.R158Afs*12 | Frame Shift Del (DEL) | VAF 55/255 reads (22%) | catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by mutect2, pindel, varscan2
- TRIM27 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.73); catalogued as COSV101019354; called by muse, mutect2
- TTBK1 | c.2437C>G p.Q813E | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV52496273; called by muse, mutect2
- TUBGCP4 | c.1816G>T p.E606* (on ENST00000260383 / NM_001286414.3; = p.E605* on NM_014444.5) | Nonsense Mutation (SNP) | VAF 39/259 reads (15%) | catalogued as COSV99539498; called by muse, mutect2, varscan2
- USH2A | c.9887G>A p.G3296D | Missense Mutation (SNP) | VAF 121/465 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1411825525, COSV56443294; called by muse, mutect2, varscan2
- VPS41 | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs199785004, COSV59649346; called by muse, mutect2, varscan2
- WDR62 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 73/429 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1568328337, COSV99543164; called by muse, mutect2, varscan2
- XAB2 | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV50364072; called by muse, mutect2, varscan2
- ZNF268 | c.2597G>T p.C866F | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99935113; called by muse, mutect2
- ZNF404 | c.1040G>T p.R347I | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV60987749, COSV60988175; called by muse, mutect2, varscan2
- ZNF438 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 31/329 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs1411138707; called by muse, mutect2
- ZNF626 | c.1266G>C p.E422D | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs1555769237, COSV74128913; called by muse, mutect2
- ZNF705B | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 53/417 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1326098438; called by muse, mutect2, varscan2
- ZZEF1 | c.5275G>C p.D1759H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV67560315; called by muse, mutect2
- ABCA10 | c.4426C>A p.P1476T | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ABCA13 | c.11881C>G p.Q3961E | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAM11 | c.2048G>T p.R683L | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2
- ADAMTS16 | c.2549del p.G850Vfs*41 | Frame Shift Del (DEL) | VAF 35/250 reads (14%) | called by mutect2, pindel, varscan2
- ADCY8 | c.759G>T p.M253I | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- ADGRA1 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- ADGRD2 | c.2016C>G p.I672M | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ADGRG4 | c.6254C>A p.P2085Q | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.675); called by muse, mutect2
- AFF2 | c.3706C>A p.P1236T | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARAP1 | c.3988-3C>T | Splice Region (SNP) | VAF 44/285 reads (15%) | called by muse, mutect2, varscan2
- BMP5 | c.77A>T p.K26I | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- BPI | c.1461A>C p.K487N (on ENST00000262865; = p.K483N on NM_001725.3) | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRK1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- C19orf44 | c.1727C>G p.A576G | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, varscan2
- C1orf116 | c.1211del p.P404Lfs*24 | Frame Shift Del (DEL) | VAF 95/394 reads (24%) | called by mutect2, pindel, varscan2
- C1orf68 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- C2CD3 | c.6400G>C p.E2134Q | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- CAPS2 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- CCDC120 | c.1879G>T p.G627W | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CDC25A | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CHD8 | c.4927G>C p.E1643Q (on ENST00000646647 / NM_001170629.2; = p.E1364Q on NM_020920.4) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CNTN5 | c.280A>C p.S94R | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.601); called by muse, mutect2
- COL6A2 | c.2746C>A p.H916N | Missense Mutation (SNP) | VAF 58/588 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CSMD3 | c.10406G>T p.G3469V (on ENST00000297405 / NM_001363185.1; = p.G3300V on NM_052900.3) | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DEPDC5 | c.2615C>T p.P872L (on ENST00000400246; = p.P941L on NM_014662.5) | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAAF2 | c.1100A>T p.E367V | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DNAH2 | c.7319T>A p.V2440E | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.296); called by muse, mutect2
- DNHD1 | c.11003C>G p.S3668* | Nonsense Mutation (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- DOCK11 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMILIN3 | c.1937C>A p.A646D | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- FAM120A | c.2893G>C p.G965R | Missense Mutation (SNP) | VAF 97/353 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM135B | c.3847A>T p.R1283W | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM13A | c.1639C>T p.Q547* | Nonsense Mutation (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- FBXO21 | c.1431_1435dup p.I479Sfs*12 (on ENST00000330622 / NM_033624.3; = p.I472Sfs*12 on NM_015002.3) | Frame Shift Ins (INS) | VAF 39/211 reads (18%) | called by mutect2, pindel, varscan2
- FGF2 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); called by muse, mutect2
- FRAS1 | c.6145G>C p.V2049L | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FSD1L | c.524C>G p.T175S | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.18907G>T p.E6303* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- GABRG3 | c.802G>C p.V268L | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GABRQ | c.1271C>G p.A424G | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- GAN | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 29/416 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- GIGYF2 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 31/328 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.687); called by muse, mutect2
- GPC3 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 21/282 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.038); called by muse, mutect2
- GPR75 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); called by muse, mutect2
- HOXA1 | c.517C>G p.L173V | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.937); called by muse, mutect2
- HOXD13 | c.169_205del p.A57Rfs*27 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel
- HUWE1 | c.4485G>C p.L1495F | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ICE1 | c.5151T>A p.C1717* | Nonsense Mutation (SNP) | VAF 24/310 reads (8%) | called by muse, mutect2
- IER5 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2
- IGKV2D-26 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 91/359 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- IGKV3D-20 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- IL16 | c.1124A>T p.Y375F | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- IL21R | c.284G>C p.S95T | Missense Mutation (SNP) | VAF 46/500 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- ITGA2 | c.1945T>C p.S649P | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- KALRN | c.8881C>T p.R2961C (on ENST00000360013 / NM_001024660.4; = p.R1264C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNH5 | c.641A>T p.K214I | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNJ13 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 35/365 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- KEAP1 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF27 | c.3238del p.Q1080Rfs*22 | Frame Shift Del (DEL) | VAF 46/260 reads (18%) | called by mutect2, pindel, varscan2
- KLHL33 | c.1024T>G p.Y342D | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KNTC1 | c.485T>C p.F162S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KRBOX4 | c.430C>T p.P144S (on ENST00000344302 / NM_001129898.2; = p.P139S on NM_017776.2) | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.221); called by muse, mutect2
- KRT26 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 36/466 reads (8%) | called by muse, mutect2
- LAYN | c.902_903del p.A301Gfs*4 (on ENST00000375615 / NM_001258390.1; = p.A293Gfs*4 on NM_178834.5) | Frame Shift Del (DEL) | VAF 28/225 reads (12%) | called by mutect2, pindel, varscan2
- LRRTM3 | c.594G>T p.R198S | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAGEB16 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MEP1A | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MIGA1 | c.1784G>T p.R595L | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by mutect2, varscan2
- MRC1 | c.1873T>A p.C625S | Missense Mutation (SNP) | VAF 102/462 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MRPL45 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTMR9 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC12 | c.1102del p.H368Tfs*183 (on ENST00000379442; = p.H225Tfs*183 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 69/450 reads (15%) | called by mutect2, pindel, varscan2
- MVB12B | c.597C>A p.D199E | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.011); called by muse, mutect2
- MXRA8 | c.1139C>G p.S380* | Nonsense Mutation (SNP) | VAF 22/254 reads (9%) | called by muse, mutect2
- MYH15 | c.4505A>G p.E1502G | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- NKX6-3 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- NLRC4 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- NPNT | c.173-1G>C p.X58_splice | Splice Site (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- NUP188 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 25/303 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2
- NUTF2 | c.174C>G p.S58R | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2
- OR2AJ1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- OR2K2 | c.350C>T p.S117F (on ENST00000374428; = p.S88F on NM_205859.2) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2
- OR2M5 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 105/376 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR4C15 | c.253T>C p.F85L (on ENST00000314644; = p.F31L on NM_001001920.2) | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- OR8S1 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 81/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OTOGL | c.4131A>T p.E1377D (on ENST00000547103; = p.E1368D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PALM3 | c.1567G>A p.E523K (on ENST00000340790; = p.E538K on NM_001145028.2) | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PDE3B | c.19G>T p.D7Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PLPPR5 | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.624); called by muse, mutect2
- POLR1A | c.658A>G p.N220D | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PRKCB | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- PRKD3 | c.2470G>C p.D824H | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2
- PTK7 | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PZP | c.2928T>G p.Y976* | Nonsense Mutation (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- RAPH1 | c.1565C>T p.S522L (on ENST00000319170 / NM_213589.3; = p.S574L on NM_203365.4) | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.084); called by muse, mutect2
- RBM10 | c.2200G>T p.G734W | Missense Mutation (SNP) | VAF 108/321 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RECQL5 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RECQL5 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 25/210 reads (12%) | called by muse, mutect2, varscan2
- REV1 | c.999C>G p.S333R | Missense Mutation (SNP) | VAF 23/306 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); called by muse, mutect2
- REV1 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RGR | c.236+1G>T p.X79_splice | Splice Site (SNP) | VAF 56/522 reads (11%) | called by muse, mutect2, varscan2
- RIT2 | c.23G>C p.S8T | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RNF185 | c.126C>A p.C42* | Nonsense Mutation (SNP) | VAF 40/342 reads (12%) | called by muse, varscan2
- ROBO2 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2
- RTL5 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 62/353 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SALL1 | c.2660C>T p.S887L | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.219); called by muse, mutect2
- SCG2 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2
- SCG2 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 25/303 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- SCML2 | c.976A>T p.T326S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.277); called by muse, mutect2
- SCN11A | c.4101C>G p.I1367M | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2
- SEMA5A | c.2801C>A p.T934N | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SHTN1 | c.1387A>T p.R463* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- SKOR2 | c.1370C>A p.A457E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC6A12 | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC8A1 | c.1612G>T p.G538C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT2 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SOS1 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- STK17B | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SULT1C3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2
- SYNJ1 | c.1649C>T p.S550L | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.234); called by muse, mutect2
- TCTN2 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 41/389 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TDRD15 | c.4599G>T p.M1533I | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLL1 | c.3011G>T p.R1004I | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TLR5 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM168 | c.98T>G p.V33G | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2
- TMPRSS6 | c.939del p.F314Sfs*15 | Frame Shift Del (DEL) | VAF 32/323 reads (10%) | called by mutect2, pindel, varscan2
- TNFAIP6 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAM1 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.309); called by muse, mutect2
- TRIM51GP | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- USP11 | c.1897A>T p.N633Y (on ENST00000218348; = p.N590Y on NM_001371072.1) | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- USP9X | c.5818A>G p.R1940G | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- VPS13B | c.4178C>T p.S1393F | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2
- WNT10A | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- XRCC1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- ZDBF2 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2
- ZFYVE9 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZNF33A | c.634C>T p.Q212* (on ENST00000458705 / NM_006974.3; = p.Q213* on NM_006954.2) | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2, varscan2
- ZNF441 | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- ZSCAN16 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ABCC5 | c.753G>T p.R251= | Silent (SNP) | VAF 26/431 reads (6%) | catalogued as COSV99657820; called by muse, mutect2
- ACSM4 | c.1053C>T p.N351= | Silent (SNP) | VAF 41/235 reads (17%) | called by muse, mutect2, varscan2
- ALDH16A1 | c.1965G>A p.L655= | Silent (SNP) | VAF 46/217 reads (21%) | called by muse, mutect2, varscan2
- ANKRD26 | c.897G>T p.V299= | Silent (SNP) | VAF 33/374 reads (9%) | called by muse, mutect2
- ARRDC2 | c.285G>A p.E95= | Silent (SNP) | VAF 31/284 reads (11%) | called by muse, mutect2, varscan2
- ATP2A1 | c.78G>T p.P26= | Silent (SNP) | VAF 48/699 reads (7%) | called by muse, mutect2
- ATP6V1E1 | c.243C>G p.L81= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- AURKAIP1 | c.28C>T p.L10= | Silent (SNP) | VAF 13/225 reads (6%) | called by muse, mutect2
- C7 | c.843C>T p.S281= | Silent (SNP) | VAF 15/228 reads (7%) | called by muse, mutect2
- CABCOCO1 | c.294G>A p.V98= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as rs986384663; called by muse, mutect2, varscan2
- CDH6 | c.1212C>A p.S404= | Silent (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.561G>T p.T187= | Silent (SNP) | VAF 124/488 reads (25%) | catalogued as rs756635555; called by muse, mutect2, varscan2
- CHAT | c.66A>C p.G22= | Silent (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- CHRND | c.1497C>A p.P499= | Silent (SNP) | VAF 157/448 reads (35%) | catalogued as COSV99286048; called by muse, mutect2, varscan2
- CMIP | c.687C>T p.I229= (on ENST00000537098 / NM_198390.2; = p.I135= on NM_030629.3) | Silent (SNP) | VAF 24/470 reads (5%) | catalogued as rs780410274; called by muse, mutect2
- CNOT1 | c.774C>T p.F258= | Silent (SNP) | VAF 38/521 reads (7%) | catalogued as rs1287927093; called by muse, mutect2
- CPT1C | c.564G>A p.E188= | Silent (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- CSMD1 | c.4074C>A p.I1358= (on ENST00000520002; = p.I1357= on NM_033225.6) | Silent (SNP) | VAF 61/294 reads (21%) | called by muse, mutect2, varscan2
- DDX3X | c.1701G>T p.P567= (on ENST00000399959; = p.P568= on NM_001356.5) | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- E2F8 | c.969T>C p.S323= | Silent (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- ELFN1 | c.162C>A p.I54= | Silent (SNP) | VAF 31/395 reads (8%) | called by muse, mutect2
- FAM50A | c.105C>T p.I35= | Silent (SNP) | VAF 22/308 reads (7%) | catalogued as COSV50132237; called by muse, mutect2
- FARSB | c.33C>G p.L11= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV56051151; called by muse, mutect2
- FFAR3 | c.165C>G p.L55= | Silent (SNP) | VAF 55/1262 reads (4%) | called by muse, mutect2
- FGD1 | c.1560C>A p.I520= | Silent (SNP) | VAF 28/242 reads (12%) | called by muse, mutect2, varscan2
- GLRA3 | c.537C>A p.P179= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs746585506; called by muse, mutect2, varscan2
- GPATCH8 | c.4302C>T p.L1434= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs767299095; called by mutect2, varscan2
- INVS | c.6C>T p.N2= | Silent (SNP) | VAF 26/474 reads (5%) | called by muse, mutect2
- IRGC | c.1149C>A p.T383= | Silent (SNP) | VAF 24/396 reads (6%) | called by muse, mutect2
- JUND | c.423C>A p.V141= | Silent (SNP) | VAF 21/421 reads (5%) | called by muse, mutect2
- LAMA1 | c.4005C>T p.I1335= | Silent (SNP) | VAF 47/406 reads (12%) | called by muse, mutect2, varscan2
- MAD1L1 | c.1722C>T p.L574= | Silent (SNP) | VAF 44/532 reads (8%) | catalogued as rs990092839; called by muse, mutect2
- MAP2 | c.2742G>A p.L914= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- MED12 | c.4692C>T p.I1564= | Silent (SNP) | VAF 31/217 reads (14%) | called by muse, mutect2, varscan2
- MKLN1 | c.2130C>G p.L710= | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- MRC1 | c.1872G>A p.V624= | Silent (SNP) | VAF 101/460 reads (22%) | called by muse, mutect2, varscan2
- NUDT6 | c.618G>T p.L206= | Silent (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- OR4C6 | c.285C>T p.C95= | Silent (SNP) | VAF 55/363 reads (15%) | catalogued as rs769822345; called by muse, mutect2, varscan2
- PJA1 | c.1776G>A p.E592= (on ENST00000361478 / NM_145119.4; = p.E404= on NM_022368.5) | Silent (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- POMT2 | c.1260C>T p.S420= | Silent (SNP) | VAF 43/462 reads (9%) | called by muse, mutect2
- PPIP5K1 | c.4047G>A p.L1349= (on ENST00000396923; = p.L1324= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 28/354 reads (8%) | called by muse, mutect2
- PTCHD4 | c.1674G>T p.L558= | Silent (SNP) | VAF 30/169 reads (18%) | called by muse, mutect2, varscan2
- PTPRT | c.945C>A p.I315= | Silent (SNP) | VAF 49/376 reads (13%) | catalogued as COSV61995261; called by muse, mutect2, varscan2
- QRFPR | c.207G>A p.V69= | Silent (SNP) | VAF 32/420 reads (8%) | catalogued as rs1417385973; called by muse, mutect2
- RASA4B | c.795C>A p.P265= | Silent (SNP) | VAF 62/1416 reads (4%) | called by muse, mutect2
- REG1A | c.135C>T p.S45= | Silent (SNP) | VAF 128/541 reads (24%) | catalogued as rs11557479; called by muse, mutect2, varscan2
- RSPO4 | c.204G>A p.K68= | Silent (SNP) | VAF 83/339 reads (24%) | called by muse, mutect2, varscan2
- RYR2 | c.11820G>T p.L3940= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as COSV100768070; called by muse, mutect2, varscan2
- SLC10A4 | c.144C>T p.L48= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- SLC45A2 | c.858G>A p.Q286= | Silent (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- SLFN13 | c.2580G>C p.L860= | Silent (SNP) | VAF 39/446 reads (9%) | called by muse, mutect2
- SLFN5 | c.2235C>T p.L745= | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as COSV55483618; called by muse, mutect2
- SOX3 | c.372C>T p.S124= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs1272755840; called by muse, mutect2
- SPATA18 | c.144C>T p.A48= | Silent (SNP) | VAF 9/188 reads (5%) | called by muse, mutect2
- SPATA33 | c.15C>T p.A5= | Silent (SNP) | VAF 62/169 reads (37%) | catalogued as rs1313538545; called by muse, mutect2, varscan2
- SPRING1 | c.93C>T p.L31= | Silent (SNP) | VAF 17/183 reads (9%) | called by muse, mutect2
- ST8SIA6 | c.802C>T p.L268= | Silent (SNP) | VAF 20/280 reads (7%) | catalogued as rs772861188; called by muse, mutect2
- STRN | c.1941A>G p.Q647= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as rs575728482; called by muse, mutect2, varscan2
- TC2N | c.984C>T p.L328= | Silent (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2, varscan2
- TECR | c.549C>T p.L183= | Silent (SNP) | VAF 67/447 reads (15%) | called by muse, mutect2, varscan2
- TRIL | c.2107C>T p.L703= | Silent (SNP) | VAF 48/230 reads (21%) | called by muse, mutect2, varscan2
- UHRF1 | c.2346C>T p.L782= (on ENST00000612630 / NM_001290050.1; = p.L795= on NM_013282.4) | Silent (SNP) | VAF 40/232 reads (17%) | called by muse, varscan2
- USP17L2 | c.540C>T p.H180= | Silent (SNP) | VAF 29/271 reads (11%) | called by mutect2, varscan2
- AL132655.6 | chr20:58840071 G>T | 5'Flank (SNP) | VAF 53/304 reads (17%) | called by muse, mutect2, varscan2
- ALG3 | c.*42C>T | 3'UTR (SNP) | VAF 17/234 reads (7%) | catalogued as rs1319266811; called by muse, mutect2
- C2CD3 | c.5882-321G>A | Intron (SNP) | VAF 41/442 reads (9%) | called by muse, mutect2
- CHEK2 | c.*43C>G | 3'UTR (SNP) | VAF 26/253 reads (10%) | catalogued as rs1302559996, COSV60422518; called by muse, mutect2, varscan2
- CHRNA4 | c.*340C>G | 3'UTR (SNP) | VAF 28/410 reads (7%) | catalogued as rs1555836696; called by muse, mutect2
- CTSH | c.123+25G>A | Intron (SNP) | VAF 17/248 reads (7%) | called by muse, mutect2
- EML4 | chr2:42333848 G>C | 3'Flank (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- FAM86C1P | n.216C>T | RNA (SNP) | VAF 42/463 reads (9%) | catalogued as rs1197133519; called by muse, mutect2
- FARP2 | c.1411+898G>T | Intron (SNP) | VAF 28/325 reads (9%) | called by muse, mutect2
- FRMPD2B | n.833C>G | RNA (SNP) | VAF 14/118 reads (12%) | called by mutect2, varscan2
- GABRA1 | c.-16+580T>A | Intron (SNP) | VAF 33/174 reads (19%) | catalogued as COSV99195709; called by muse, mutect2, varscan2
- GCNT2 | chr6:10633938 T>A | 3'Flank (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- HERC2P2 | n.2783C>T | RNA (SNP) | VAF 41/498 reads (8%) | called by muse, mutect2
- ING1 | chr13:110712798 C>G | 5'Flank (SNP) | VAF 18/251 reads (7%) | called by muse, mutect2
- ITGA7 | c.670+16G>T | Intron (SNP) | VAF 47/217 reads (22%) | called by muse, mutect2, varscan2
- JAZF1-AS1 | n.754G>T | RNA (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- KCNAB3 | c.242+9del | Intron (DEL) | VAF 29/195 reads (15%) | catalogued as rs1392160843; called by mutect2, pindel, varscan2
- KCNMA1 | c.2267-4478C>A | Intron (SNP) | VAF 13/214 reads (6%) | called by muse, mutect2
- LPAL2 | chr6:160511011 G>A | 5'Flank (SNP) | VAF 37/414 reads (9%) | called by muse, mutect2
- MGAM | c.4619-12097G>T | Intron (SNP) | VAF 107/395 reads (27%) | called by muse, mutect2, varscan2
- NDUFAF6 | c.*12G>T | 3'UTR (SNP) | VAF 13/102 reads (13%) | catalogued as rs1163224347; called by muse, mutect2
- NDUFV1 | chr11:67604414 A>T | 5'Flank (SNP) | VAF 29/209 reads (14%) | catalogued as rs1337211722; called by muse, mutect2, varscan2
- NOC2LP2 | n.1454G>T | RNA (SNP) | VAF 131/477 reads (27%) | called by muse, mutect2, varscan2
- NPR3 | c.*3307C>T | 3'UTR (SNP) | VAF 25/307 reads (8%) | called by muse, mutect2
- OR7E5P | n.581A>G | RNA (SNP) | VAF 57/403 reads (14%) | called by muse, mutect2, varscan2
- OTOAP1 | n.2470C>A | RNA (SNP) | VAF 36/1258 reads (3%) | called by muse, mutect2
- PCTP | c.141+189G>T | Intron (SNP) | VAF 15/208 reads (7%) | catalogued as rs925168092; called by muse, mutect2
- PML | c.1710+1288C>T | Intron (SNP) | VAF 26/262 reads (10%) | called by muse, mutect2, varscan2
- POLR2I | c.-18C>T | 5'UTR (SNP) | VAF 28/300 reads (9%) | catalogued as rs745611800; called by muse, mutect2
- PRKCB | c.174-10G>T | Intron (SNP) | VAF 60/320 reads (19%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1429-823G>T | Intron (SNP) | VAF 23/221 reads (10%) | called by muse, mutect2, varscan2
- RBM3 | chrX:48574619 G>T | 5'Flank (SNP) | VAF 36/480 reads (8%) | called by muse, mutect2
- RIMS2 | c.698+52926A>C | Intron (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2
- SDHA | c.1260+43G>T | Intron (SNP) | VAF 47/478 reads (10%) | called by muse, mutect2, varscan2
- SPATA20 | c.77+475C>T | Intron (SNP) | VAF 91/578 reads (16%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-4212C>A | Intron (SNP) | VAF 23/240 reads (10%) | called by muse, mutect2
- SSPOP | n.9294C>T | RNA (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- STMP1 | chr7:135660184 G>A | 5'Flank (SNP) | VAF 27/303 reads (9%) | catalogued as rs757311868; called by muse, mutect2
- TBX2 | chr17:61412515 C>A | 3'Flank (SNP) | VAF 14/111 reads (13%) | catalogued as rs1016662155; called by muse, mutect2, varscan2
- TENM1 | c.3696-5256T>A | Intron (SNP) | VAF 12/152 reads (8%) | catalogued as COSV64448583; called by muse, mutect2
- TMEM135 | c.*2326A>C | 3'UTR (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2
- TNNI3K | c.1773-17911G>T | Intron (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2
- TPM4 | c.*306G>C | 3'UTR (SNP) | VAF 24/296 reads (8%) | called by muse, mutect2
- TPM4 | c.*446G>A | 3'UTR (SNP) | VAF 19/216 reads (9%) | called by muse, varscan2
- ZFAND1 | c.-3G>A | 5'UTR (SNP) | VAF 41/313 reads (13%) | catalogued as rs1401876028; called by muse, mutect2, varscan2
- ZNF99 | c.*3110A>T | 3'UTR (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
